Somatic mutation profile of tumor specimen TCGA-85-A4JB-01A (aliquot TCGA-85-A4JB-01A-51D-A25L-08) from TCGA case TCGA-85-A4JB, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.8 years (27,315 days).
Specimen TCGA-85-A4JB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 968ce40e-4c9f-4ef6-9392-619b7a1f57cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A4JB-10A (Blood Derived Normal), aliquot TCGA-85-A4JB-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef484d31-5a4c-4941-8f72-83099b92ebe1

The open-access MAF lists 509 somatic variants for this specimen: 395 protein-altering or splice-affecting, 103 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 340, Silent 103, Nonsense Mutation 21, Frame Shift Del 17, Splice Site 11, Intron 5, Splice Region 3, RNA 2, 5'UTR 2, Translation Start Site 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797del p.G266Dfs*79 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs1567548223, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AATK | c.2603C>A p.S868* (on ENST00000326724 / NM_001080395.3; = p.S765* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100353394, COSV58364339; called by muse, mutect2, varscan2
- ABCC9 | c.1055A>T p.Y352F | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.122); catalogued as COSV99687646; called by muse, mutect2, varscan2
- ABCG8 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs142346631, COSV55394571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABL2 | c.1535del p.P512Lfs*7 (on ENST00000502732 / NM_007314.4; = p.P497Lfs*7 on NM_005158.5) | Frame Shift Del (DEL) | VAF 16/140 reads (11%) | catalogued as rs753365868, COSV61019281; called by mutect2, pindel, varscan2
- ABLIM3 | c.1504T>C p.F502L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.345); catalogued as COSV100448872; called by muse, mutect2, varscan2
- ACAA2 | c.446G>C p.W149S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV99552057; called by muse, mutect2, varscan2
- ACTR5 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.609); catalogued as COSV99710289; called by muse, mutect2, varscan2
- ACVR1B | c.1035A>T p.K345N | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV99232132; called by muse, mutect2, varscan2
- ADAM18 | c.1756T>A p.S586T | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.281); catalogued as COSV99696229; called by muse, mutect2, varscan2
- ADAM28 | c.1380G>T p.K460N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV56098986, COSV99740082; called by muse, mutect2, varscan2
- ADAMTS12 | c.2668G>T p.E890* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV61257941; called by muse, mutect2, varscan2
- ADAR | c.1042A>G p.T348A | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1456341426, COSV99426904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRB3 | c.3328G>T p.A1110S | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV99486182; called by muse, mutect2, varscan2
- ADGRL3 | c.3130G>A p.E1044K (on ENST00000506720 / NM_001322402.2; = p.E976K on NM_015236.6) | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); catalogued as COSV101547441; called by muse, mutect2, varscan2
- ADGRV1 | c.4209G>T p.L1403F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.114); catalogued as COSV101316667; called by muse, mutect2, varscan2
- AGTR1 | c.820T>A p.C274S | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100837223; called by muse, mutect2, varscan2
- AL133500.1 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.13); catalogued as COSV99860510; called by muse, mutect2, varscan2
- ALDH6A1 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201279537, COSV100620988; called by muse, mutect2, varscan2
- ALPP | c.1400A>T p.Q467L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV101235206; called by muse, mutect2, varscan2
- AMER3 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs760195858, COSV58466344; called by muse, mutect2, varscan2
- AMPD2 | c.2078A>G p.N693S | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.66); catalogued as COSV99858217; called by muse, mutect2, varscan2
- ANGEL1 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.598); catalogued as COSV99200369; called by muse, mutect2, varscan2
- ARAP1 | c.4334C>G p.S1445C (on ENST00000393609 / NM_001040118.2; = p.S1200C on NM_015242.4) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100502282; called by muse, mutect2, varscan2
- ARFIP2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.339); catalogued as COSV99601717; called by muse, mutect2, varscan2
- ARHGAP44 | c.1507T>C p.F503L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); catalogued as COSV99311695; called by muse, mutect2, varscan2
- ARHGAP44 | c.2417A>G p.K806R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV99311696; called by muse, mutect2, varscan2
- ARPP21 | c.1237T>G p.S413A | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99493724; called by muse, mutect2, varscan2
- ASAH2 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as COSV100270200; called by muse, mutect2, varscan2
- ASTN1 | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56065438, COSV56092745; called by muse, mutect2
- ATP8A1 | c.922A>G p.M308V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV100047531; called by muse, mutect2, varscan2
- BNC2 | c.2562C>G p.N854K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101034730; called by muse, mutect2, varscan2
- BRINP3 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 82/340 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV66513604, COSV66513646; called by muse, varscan2
- BRINP3 | c.1781C>G p.P594R | Missense Mutation (SNP) | VAF 89/324 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100819606; called by muse, varscan2
- BTBD9 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV100023012; called by muse, mutect2
- BTN2A1 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs374472452, COSV100438831; called by muse, mutect2, varscan2
- C14orf39 | c.536C>G p.T179S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100408185; called by muse, mutect2, varscan2
- CA2 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV99570384; called by muse, mutect2, varscan2
- CA2 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV53406052, COSV53408449, COSV99570386; called by muse, mutect2, varscan2
- CACHD1 | c.1699G>T p.V567L | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs556698065, COSV99263546; called by muse, mutect2, varscan2
- CAMSAP2 | c.1190G>T p.R397M (on ENST00000236925 / NM_001297707.2; = p.R386M on NM_203459.3) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV99374538; called by muse, mutect2, varscan2
- CARD11 | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101211076, COSV67802724; called by muse, mutect2, varscan2
- CASS4 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs1238384019, COSV100824996; called by muse, mutect2, varscan2
- CBLB | c.939C>G p.N313K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99914609; called by muse, mutect2, varscan2
- CCDC144A | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as rs1156932674; called by muse, mutect2, varscan2
- CCDC34 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.28); catalogued as COSV100156728; called by muse, mutect2, varscan2
- CCDC73 | c.2099T>G p.V700G | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.124); catalogued as COSV100068504; called by muse, mutect2, varscan2
- CCDC73 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV100068506; called by muse, mutect2, varscan2
- CCNY | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.315); catalogued as COSV99591253; called by muse, mutect2
- CCNYL1 | c.382C>G p.L128V (on ENST00000295414 / NM_001330218.2; = p.L58V on NM_152523.2) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as COSV99776115; called by muse, mutect2, varscan2
- CDIN1 | c.803G>T p.C268F (on ENST00000437989; = p.C170F on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.461); catalogued as COSV100590118; called by muse, mutect2, varscan2
- CDK13 | c.3923A>G p.Q1308R | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV99476202; called by muse, mutect2, varscan2
- CDRT1 | c.1717C>A p.H573N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100600013; called by muse, mutect2, varscan2
- CDX2 | c.628T>C p.Y210H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101122724; called by muse, mutect2, varscan2
- CELSR3 | c.3134C>T p.P1045L | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99375355; called by muse, mutect2, varscan2
- CENPE | c.5716G>T p.D1906Y | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs767613874, COSV99479475; called by muse, mutect2, varscan2
- CENPE | c.2132-2A>G p.X711_splice | Splice Site (SNP) | VAF 31/69 reads (45%) | catalogued as COSV99479477; called by muse, mutect2, varscan2
- CENPJ | c.3989G>A p.G1330D | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196634965, COSV55038401, COSV99694700; called by muse, mutect2, varscan2
- CENPJ | c.3988G>T p.G1330C | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99694704; called by muse, mutect2, varscan2
- CEP192 | c.4450G>T p.V1484F | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382354, COSV58069669; called by muse, mutect2, varscan2
- CFAP61 | c.2584C>A p.R862S | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99846976; called by muse, mutect2
- CHFR | c.1722G>T p.M574I (on ENST00000432561 / NM_001161345.1; = p.M533I on NM_018223.2) | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99905839; called by muse, mutect2, varscan2
- CHODL | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs556962391, COSV54732660, COSV54735705; called by muse, mutect2, varscan2
- CHRM2 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV57782890, COSV57784898; called by muse, mutect2, varscan2
- CHRNA4 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV100937273, COSV100937286; called by muse, mutect2, varscan2
- CHRNA7 | c.265T>A p.W89R | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100181859; called by muse, mutect2, varscan2
- CLSTN2 | c.1154T>A p.M385K | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101515947; called by muse, varscan2
- CNGB3 | c.756C>A p.Y252* | Nonsense Mutation (SNP) | VAF 41/121 reads (34%) | catalogued as COSV100183290; called by muse, mutect2, varscan2
- CNTNAP4 | c.2376G>C p.W792C | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100273717; called by muse, mutect2, varscan2
- COG2 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100794820, COSV64186135; called by muse, mutect2, varscan2
- COL12A1 | c.3280A>G p.K1094E | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.123); catalogued as COSV100486773; called by muse, mutect2, varscan2
- COL22A1 | c.1831G>T p.G611W | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57326392; called by muse, mutect2, varscan2
- COL4A5 | c.1174G>T p.V392F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.263); catalogued as COSV100090483; called by muse, mutect2, varscan2
- COL6A3 | c.2207G>T p.G736V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99802275; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2819G>T p.G940V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99267901; called by muse, mutect2, varscan2
- CPA2 | c.1208C>A p.T403N | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99744354; called by muse, mutect2
- CPA6 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99915141; called by muse, mutect2, varscan2
- CPED1 | c.592T>C p.C198R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100121677; called by muse, mutect2
- CSMD3 | c.1278G>T p.R426S | Missense Mutation (SNP) | VAF 102/238 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99851159; called by muse, mutect2, varscan2
- CTAGE1 | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 76/336 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.376); catalogued as rs780898304, COSV101194577; called by muse, mutect2, varscan2
- CTNND2 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs141302945; called by muse, mutect2, varscan2
- CYSLTR2 | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.493); catalogued as rs1311415009, COSV99935462; called by muse, mutect2, varscan2
- DCAF12L1 | c.1136C>A p.A379D | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100948483; called by muse, mutect2, varscan2
- DCAF8 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs768015097, COSV100470970; called by muse, mutect2, varscan2
- DDX3X | c.1907-1G>T p.X636_splice (on ENST00000399959; = p.X637_splice on NM_001356.5) | Splice Site (SNP) | VAF 19/55 reads (35%) | catalogued as COSV101302536; called by muse, mutect2, varscan2
- DEAF1 | c.1610A>C p.Q537P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99448975; called by muse, mutect2, varscan2
- DEFB118 | c.163T>A p.C55S | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568725395, COSV99489418; called by muse, mutect2, varscan2
- DEPDC5 | c.3586G>A p.V1196M (on ENST00000400246; = p.V1265M on NM_014662.5) | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56698974, COSV99836837; called by muse, mutect2, varscan2
- DIAPH1 | c.1031A>G p.H344R | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV99527385; called by muse, mutect2, varscan2
- DIRAS2 | c.421C>A p.R141S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV101005930; called by muse, mutect2, varscan2
- DLG1 | c.2565G>C p.E855D (on ENST00000419354 / NM_001290983.1; = p.E877D on NM_004087.2) | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100016176; called by muse, mutect2
- DLGAP5 | c.1447A>T p.K483* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as COSV99904220; called by muse, mutect2, varscan2
- DNAH9 | c.6137C>A p.A2046D | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308772; called by muse, mutect2, varscan2
- DNM2 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118198; called by muse, mutect2, varscan2
- DOCK6 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs188066183, COSV99371062, COSV99371138; called by muse, varscan2
- DPYSL4 | c.40-2A>G p.X14_splice | Splice Site (SNP) | VAF 16/49 reads (33%) | catalogued as rs771538881, COSV100634077; called by muse, mutect2, varscan2
- DYM | c.807A>T p.K269N | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs1178039019, COSV99494414; called by muse, mutect2, varscan2
- E2F7 | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100524070; called by muse, mutect2, varscan2
- EDA | c.707-2A>T p.X236_splice | Splice Site (SNP) | VAF 19/47 reads (40%) | catalogued as CS113718, CS982168, COSV101000181; called by muse, mutect2, varscan2
- EIF2S3 | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV99451199; called by muse, mutect2, varscan2
- ELK1 | c.775G>T p.V259F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.058); catalogued as COSV99902413; called by muse, mutect2, varscan2
- EPN3 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs371253163; called by muse, mutect2, varscan2
- ERV3-1 | c.1204T>C p.W402R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV99276240; called by mutect2, varscan2
- ERVW-1 | c.760T>G p.W254G | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.264); catalogued as COSV101423880; called by muse, mutect2, varscan2
- EYA4 | c.725-1G>T p.X242_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100766517; called by muse, mutect2
- FABP2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV99917031; called by muse, mutect2, varscan2
- FAM47C | c.1900C>A p.P634T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782084813, COSV100793011; called by muse, mutect2, varscan2
- FAM83B | c.2522G>C p.S841T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV100175184; called by muse, mutect2, varscan2
- FAT1 | c.7252G>T p.D2418Y | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499688; called by muse, mutect2, varscan2
- FAT3 | c.12692C>A p.P4231H | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53120039; called by muse, mutect2, varscan2
- FBN2 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.04); catalogued as COSV99331363; called by muse, mutect2, varscan2
- FBXL18 | c.532C>A p.Q178K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101212130; called by muse, mutect2, varscan2
- FER | c.1924G>T p.G642* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99814231; called by muse, mutect2
- FER | c.1924+1G>T p.X642_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as rs1167132778, COSV99814234; called by muse, mutect2
- FGD6 | c.984A>T p.Q328H | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100676905; called by muse, mutect2, varscan2
- FIGNL1 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100794969; called by muse, mutect2, varscan2
- FLNC | c.5602G>A p.G1868S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100368957; called by muse, mutect2, varscan2
- FMR1 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 58/157 reads (37%) | catalogued as COSV99503710, COSV99503872; called by muse, mutect2, varscan2
- FNIP2 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 47/166 reads (28%) | catalogued as COSV100033399; called by muse, mutect2, varscan2
- FSHR | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100438321; called by muse, mutect2, varscan2
- FSIP1 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100618398; called by muse, mutect2, varscan2
- FZR1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs775882980, COSV58051030; called by muse, mutect2, varscan2
- GABRA2 | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62915727; called by muse, mutect2, varscan2
- GABRA5 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV100165915; called by muse, mutect2, varscan2
- GABRB3 | c.1376C>A p.T459N | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100162402; called by muse, mutect2, varscan2
- GALNT17 | c.1438G>C p.D480H | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100356756, COSV61196496; called by muse, mutect2
- GFI1 | c.228A>T p.E76D | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.142); catalogued as COSV99647682; called by muse, mutect2, varscan2
- GJD2 | c.334G>T p.V112F | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.054); catalogued as COSV99290950; called by muse, mutect2, varscan2
- GK2 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV62628682; called by muse, mutect2, varscan2
- GLDN | c.694A>T p.K232* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100118100; called by muse, mutect2, varscan2
- GRIA3 | c.2275C>A p.L759M | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99992222; called by muse, mutect2, varscan2
- H3C10 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.189); catalogued as rs1409580960, COSV100297696; called by muse, mutect2, varscan2
- HAO1 | c.947C>A p.P316Q | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101113366; called by muse, mutect2, varscan2
- HELQ | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 50/228 reads (22%) | catalogued as rs1382587261, COSV99788218; called by muse, mutect2, varscan2
- HEPACAM | c.32C>A p.A11D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV100005978; called by muse, mutect2, varscan2
- HIVEP1 | c.8071A>G p.T2691A | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101045871; called by muse, mutect2, varscan2
- HNF4G | c.1135C>A p.P379T (on ENST00000354370 / NM_001330561.2; = p.P426T on NM_004133.5) | Missense Mutation (SNP) | VAF 125/349 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.117); catalogued as COSV62966825; called by muse, mutect2, varscan2
- HR | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100456077; called by muse, mutect2, varscan2
- HSDL2 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99357188; called by muse, mutect2, varscan2
- ICE1 | c.1729G>T p.D577Y | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV99666002; called by muse, mutect2, varscan2
- IGSF9B | c.2917A>T p.S973C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100318625; called by muse, mutect2, varscan2
- IKZF2 | c.957A>T p.Q319H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100563928; called by muse, mutect2, varscan2
- IL27 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs201926026, COSV100113006, COSV60488600; called by muse, mutect2, varscan2
- IL37 | c.253T>A p.Y85N | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99636627; called by muse, mutect2, varscan2
- ILDR2 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs147213269; called by muse, mutect2, varscan2
- INHBA | c.192C>G p.N64K | Missense Mutation (SNP) | VAF 156/690 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99638536; called by muse, mutect2, varscan2
- INPP5F | c.3376C>G p.Q1126E | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV100740456; called by muse, mutect2, varscan2
- ITGA10 | c.1882G>T p.D628Y | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100995077; called by muse, mutect2, varscan2
- ITGA7 | c.2360C>T p.A787V (on ENST00000555728; = p.A743V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs765162973, COSV99165625; called by muse, mutect2, varscan2
- ITGAX | c.2213T>A p.L738Q | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99192084; called by muse, mutect2, varscan2
- JAG2 | c.3640C>A p.H1214N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100078911; called by muse, mutect2
- KASH5 | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101483526; called by muse, mutect2
- KASH5 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV101483527, COSV71358416; called by muse, mutect2
- KCNB1 | c.2527G>A p.V843M | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs749278313, COSV100870612; called by muse, mutect2, varscan2
- KCNB2 | c.691C>G p.R231G | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs367953569, COSV101579033; called by muse, mutect2, varscan2
- KCNH7 | c.2306G>T p.G769V | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100150300, COSV59797970; called by muse, mutect2, varscan2
- KCNK18 | c.568C>G p.P190A | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs372982639, COSV100572163; called by muse, mutect2, varscan2
- KCNT1 | c.380G>T p.W127L (on ENST00000488444; = p.W146L on NM_020822.3) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99706995; called by muse, mutect2, varscan2
- KDR | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV99818922; called by muse, mutect2, varscan2
- KIAA1841 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.063); catalogued as COSV99694301; called by muse, mutect2, varscan2
- KIF1C | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100297336; called by muse, mutect2
- KIF1C | c.2501G>T p.R834L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV100297337, COSV57904855; called by muse, varscan2
- KIF3A | c.515A>T p.K172I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs17854353, COSV101109529, COSV66415918; called by muse, mutect2
- KIRREL2 | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99384554; called by muse, mutect2, varscan2
- KLHL38 | c.1289A>T p.D430V | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100384665; called by muse, mutect2
- LAMA2 | c.2703T>G p.C901W | Missense Mutation (SNP) | VAF 57/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101370943; called by muse, mutect2, varscan2
- LAMB4 | c.4194G>T p.K1398N | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99226019; called by muse, mutect2, varscan2
- LAMC1 | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as COSV51152051; called by muse, mutect2, varscan2
- LAPTM5 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as rs1325841150, COSV53854789; called by muse, mutect2, varscan2
- LCT | c.4471A>G p.I1491V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV99930660; called by muse, mutect2, varscan2
- LHX8 | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV99634590; called by muse, mutect2, varscan2
- LIMK1 | c.350T>C p.F117S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV100283524; called by muse, mutect2, varscan2
- LIPE | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769577111, COSV99734501; called by muse, mutect2, varscan2
- LMNB2 | c.1814A>C p.H605P | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.945); catalogued as COSV99296144; called by muse, mutect2, varscan2
- LRCH2 | c.2211A>T p.E737D | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100407749; called by muse, mutect2, varscan2
- LRP1 | c.13337G>A p.R4446Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs750572405, COSV99677709; called by muse, mutect2, varscan2
- LRP1B | c.9271G>A p.A3091T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs769928329, COSV101262149, COSV67201387, COSV67249506; called by muse, mutect2, varscan2
- LRP1B | c.3479A>T p.K1160I | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101262150; called by muse, mutect2, varscan2
- LRP1B | c.2555G>C p.C852S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796645, COSV63341684; called by muse, mutect2, varscan2
- LRP2 | c.12686G>C p.G4229A | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV99790682; called by muse, mutect2
- LRRK2 | c.2752C>G p.R918G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV100109364, COSV100111395; called by muse, mutect2
- LYPD3 | c.568G>C p.V190L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV99747280; called by muse, mutect2, varscan2
- LYST | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101090475; called by muse, mutect2
- LZTS1 | c.854A>T p.E285V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs766535717, COSV99743435; called by muse, mutect2, varscan2
- MAGEE1 | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.84); catalogued as rs369344909, COSV100819551; called by muse, mutect2, varscan2
- MAGI1 | c.3107G>T p.C1036F (on ENST00000402939 / NM_001033057.2; = p.C1065F on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.921); catalogued as COSV100443434; called by muse, mutect2, varscan2
- MAP3K7 | c.398G>T p.W133L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100997917; called by muse, mutect2, varscan2
- MBOAT2 | c.505A>C p.R169= | Splice Region (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100020736; called by muse, mutect2, varscan2
- MED31 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV99854685; called by muse, mutect2, varscan2
- MEGF8 | c.3350C>G p.T1117R (on ENST00000251268 / NM_001271938.2; = p.T1050R on NM_001410.3) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99239670; called by muse, mutect2, varscan2
- MEIS3 | c.609G>T p.W203C | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as COSV100520596, COSV100520601; called by muse, mutect2, varscan2
- METTL22 | c.825A>T p.T275= | Splice Region (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99371978; called by muse, mutect2, varscan2
- MGAM | c.343C>A p.R115S | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101516578; called by muse, mutect2, varscan2
- MN1 | c.3058G>C p.D1020H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs968161766, COSV100180240, COSV56562647; called by muse, mutect2, varscan2
- MPDZ | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100065232; called by muse, mutect2
- MSR1 | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); catalogued as COSV100028288, COSV50513878; called by muse, mutect2, varscan2
- MUC16 | c.38225C>A p.T12742N | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV101202125; called by muse, mutect2, varscan2
- MUC16 | c.21210G>T p.E7070D | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.058); catalogued as COSV101202126; called by muse, mutect2, varscan2
- MUC16 | c.1792C>A p.P598T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV101202128; called by muse, mutect2, varscan2
- MYC | c.1114C>T p.R372W (on ENST00000377970; = p.R387W on NM_002467.6) | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV99422018; called by muse, mutect2, varscan2
- MYH8 | c.5623C>A p.Q1875K | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101238977; called by muse, mutect2, varscan2
- MYO5B | c.3276+1G>T p.X1092_splice | Splice Site (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99546566; called by muse, mutect2, varscan2
- MYO6 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.977); catalogued as COSV64118802; called by muse, mutect2, varscan2
- MYO7A | c.2032T>A p.F678I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101289320; called by muse, mutect2, varscan2
- NAALADL1 | c.1277T>C p.F426S | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100368304; called by muse, mutect2, varscan2
- NAV3 | c.212A>T p.Q71L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV57059392; called by muse, mutect2, varscan2
- NAV3 | c.6837G>T p.M2279I (on ENST00000397909 / NM_001024383.2; = p.M2257I on NM_014903.6) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV57096511, COSV99896698; called by muse, varscan2
- NCAM2 | c.1878C>A p.Y626* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as COSV99525878; called by muse, mutect2, varscan2
- NCF2 | c.625G>T p.V209L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV100838956; called by muse, mutect2
- NCKAP1L | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747238608, COSV99515839; called by muse, mutect2, varscan2
- NCKIPSD | c.1542G>T p.M514I | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV99584356; called by muse, mutect2, varscan2
- NCKIPSD | c.1541T>A p.M514K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV99584360; called by muse, varscan2
- NEFH | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.656); catalogued as rs370229372, COSV60214881; called by muse, mutect2, varscan2
- NFRKB | c.1525G>T p.V509L (on ENST00000446488 / NM_001143835.2; = p.V534L on NM_006165.3) | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV100452135; called by muse, mutect2
- NLRC5 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs768062905, COSV52648369; called by muse, mutect2, varscan2
- NLRP12 | c.686A>T p.K229M | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100146055; called by muse, mutect2, varscan2
- NLRP13 | c.2330C>A p.A777D | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV61621737; called by muse, mutect2, varscan2
- NLRP13 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100738641; called by muse, mutect2, varscan2
- NOP53 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.241); catalogued as rs770730864, COSV54409249, COSV99622309; called by muse, mutect2, varscan2
- NPAS2 | c.721A>G p.M241V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV100177159; called by muse, mutect2, varscan2
- NRXN2 | c.5063T>G p.V1688G | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV99636338; called by muse, mutect2, varscan2
- NRXN2 | c.1469C>A p.A490D | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV99636346; called by muse, mutect2, varscan2
- NUDT8 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV100039974; called by muse, mutect2, varscan2
- NUP58 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1251301016, COSV101098951; called by muse, mutect2
- OCA2 | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.023); catalogued as COSV100668872; called by muse, mutect2, varscan2
- OLFM4 | c.821G>T p.W274L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99524638; called by muse, mutect2, varscan2
- OR10AG1 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100400245; called by muse, mutect2, varscan2
- OR10G8 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV101461893; called by muse, mutect2, varscan2
- OR13G1 | c.800G>T p.R267I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV100687629, COSV62945189; called by muse, mutect2, varscan2
- OR1D2 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.907); catalogued as COSV100514030, COSV58922669; called by muse, mutect2
- OR2A14 | c.697C>A p.R233S | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101376509; called by muse, mutect2, varscan2
- OR2AG1 | c.909G>T p.R303S | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100265013; called by muse, mutect2
- OR2M5 | c.852G>T p.M284I | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs747039507, COSV100822899; called by muse, mutect2, varscan2
- OR2T34 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs1169047264, COSV100170369, COSV60901068; called by muse, mutect2, varscan2
- OR2W3 | c.850del p.L284Sfs*14 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs1268396241; called by mutect2, pindel, varscan2
- OR4C15 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100116186, COSV100116216; called by muse, mutect2, varscan2
- OR4S1 | c.482C>G p.T161R | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100180378; called by muse, mutect2, varscan2
- OR51B6 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100972206; called by muse, mutect2
- OR52E6 | c.724T>A p.C242S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100259592; called by muse, mutect2, varscan2
- OR5D18 | c.401C>A p.T134K | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100450942; called by muse, mutect2, varscan2
- OR6C3 | c.509T>A p.V170D | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as COSV101110408; called by muse, mutect2, varscan2
- OR6S1 | c.461del p.G154Dfs*62 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as COSV57838018; called by mutect2, pindel, varscan2
- OR8D1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100766687; called by muse, mutect2, varscan2
- OR8I2 | c.481T>G p.W161G | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV100135800, COSV100136293; called by muse, mutect2, varscan2
- OTUD7A | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs753263228, COSV100193396; called by muse, mutect2
- OTULINL | c.1052A>T p.Y351F | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99947417; called by muse, mutect2, varscan2
- OVCH2 | c.879G>T p.W293C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101491949; called by muse, mutect2
- OXLD1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as rs1352037075, COSV100235722, COSV100235863; called by muse, mutect2, varscan2
- PAXX | c.556A>C p.I186L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV100860484; called by muse, mutect2, varscan2
- PCDH15 | c.4691G>T p.R1564M | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as COSV100229089; called by muse, mutect2, varscan2
- PCDHA3 | c.956A>T p.Q319L | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.067); catalogued as COSV100793837; called by muse, mutect2, varscan2
- PCK1 | c.1773C>A p.D591E | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100101053; called by muse, mutect2, varscan2
- PDE6A | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV99678812; called by muse, mutect2, varscan2
- PDGFC | c.920A>C p.E307A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99926477; called by muse, mutect2, varscan2
- PDGFC | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV56855067, COSV99926479; called by muse, mutect2, varscan2
- PEPD | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV99728894; called by muse, mutect2, varscan2
- PEX19 | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 106/372 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100926996; called by muse, mutect2, varscan2
- PIGN | c.1363A>T p.I455L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV100716281; called by muse, mutect2, varscan2
- PIGQ | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV99216641; called by muse, mutect2
- PKHD1L1 | c.8111T>A p.I2704N | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV101007038; called by muse, mutect2, varscan2
- POU6F2 | c.1984C>A p.L662M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101302901; called by muse, mutect2
- PPP1R32 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 106/388 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV100088015; called by muse, mutect2, varscan2
- PRDM9 | c.1300del p.D434Ifs*30 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | catalogued as COSV99691262; called by mutect2, pindel, varscan2
- PRPF19 | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 55/217 reads (25%) | catalogued as COSV57128419, COSV99920824; called by muse, mutect2, varscan2
- PRPF31 | c.587A>T p.E196V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV100320150; called by muse, mutect2, varscan2
- PRRG3 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs1214235621, COSV64850922; called by muse, mutect2, varscan2
- PSMG2 | c.582-2A>G p.X194_splice | Splice Site (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100466728; called by muse, mutect2, varscan2
- PTCHD4 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV100261931; called by muse, mutect2, varscan2
- PTGER3 | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV100139857; called by muse, mutect2, varscan2
- PTK7 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100030778, COSV57847325; called by muse, mutect2, varscan2
- PTPN3 | c.914A>G p.H305R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99356350; called by muse, mutect2, varscan2
- RAB3IP | c.1247A>G p.Y416C (on ENST00000550536 / NM_175623.4; = p.Y400C on NM_022456.5) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1173249733, COSV99923778; called by muse, mutect2, varscan2
- RAG1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1159713387, COSV100201226; called by muse, mutect2, varscan2
- RARA | c.520T>A p.C174S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV99565554; called by muse, mutect2, varscan2
- RASAL2 | c.2870A>T p.E957V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100862984, COSV62712853; called by muse, varscan2
- RENBP | c.687+1G>T p.X229_splice | Splice Site (SNP) | VAF 46/97 reads (47%) | catalogued as COSV100130140; called by muse, mutect2, varscan2
- RET | c.2070del p.G691Vfs*40 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | catalogued as COSV60699252; called by mutect2, pindel
- REV3L | c.5078A>G p.K1693R | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.107); catalogued as COSV100725750; called by muse, mutect2, varscan2
- RHEBL1 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99987999, COSV99988076; called by muse, mutect2, varscan2
- RNF216 | c.1132C>T p.L378F (on ENST00000425013 / NM_207116.3; = p.L435F on NM_207111.4) | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767143684, COSV101111407; called by muse, mutect2, varscan2
- RNF31 | c.509G>C p.R170T | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99396348; called by muse, mutect2, varscan2
- RPL10L | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100022826; called by muse, mutect2, varscan2
- RPS6KA2 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99692508; called by muse, mutect2, varscan2
- RPS6KA2 | c.211G>T p.G71* | Nonsense Mutation (SNP) | VAF 19/106 reads (18%) | catalogued as COSV99692511; called by muse, mutect2, varscan2
- RSPO2 | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV99410649; called by muse, mutect2, varscan2
- RTTN | c.1068G>T p.M356I | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99730608; called by muse, mutect2, varscan2
- RYR3 | c.8588T>C p.L2863P (on ENST00000389232; = p.L2864P on NM_001036.6) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101215111; called by muse, mutect2
- SAP130 | c.2437G>C p.A813P | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.491); catalogued as COSV99385488; called by muse, mutect2, varscan2
- SATB2 | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99613008; called by muse, mutect2, varscan2
- SCG2 | c.1526C>A p.A509D | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100544963; called by muse, mutect2, varscan2
- SCN5A | c.1250A>T p.E417V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100351184; called by muse, mutect2, varscan2
- SEC14L4 | c.729del p.T244Pfs*2 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as COSV99742856; called by mutect2, pindel, varscan2
- SH2B1 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100451322; called by muse, mutect2, varscan2
- SHANK1 | c.2833C>T p.L945F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as rs767706284, COSV53263851, COSV99522252; called by muse, mutect2
- SIPA1L2 | c.4940G>C p.G1647A | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); catalogued as COSV99479951; called by muse, mutect2, varscan2
- SKOR1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100408733; called by muse, mutect2, varscan2
- SLC12A4 | c.2380G>T p.G794C | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99863367; called by muse, mutect2, varscan2
- SLC14A2 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV54908001; called by muse, mutect2, varscan2
- SLC2A11 | c.256G>T p.G86C (on ENST00000345044 / NM_001024938.4; = p.G93C on NM_030807.5) | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99741964; called by muse, mutect2, varscan2
- SLC38A1 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1035851969, COSV101284310; called by muse, mutect2, varscan2
- SLC39A12 | c.135C>A p.D45E | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371382920; called by muse, mutect2, varscan2
- SLC3A1 | c.403A>C p.N135H | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs745692914, COSV99577768; called by muse, mutect2, varscan2
- SLC4A4 | c.2756G>C p.G919A (on ENST00000264485 / NM_001098484.3; = p.G875A on NM_003759.4) | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99143444; called by muse, mutect2, varscan2
- SLC9A1 | c.1468T>C p.F490L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99850128; called by muse, mutect2, varscan2
- SLC9A2 | c.2122C>A p.Q708K | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99296969; called by muse, mutect2, varscan2
- SLC9A6 | c.547G>C p.A183P | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100857961; called by muse, mutect2, varscan2
- SLIT2 | c.1738G>T p.G580* | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | catalogued as COSV99888061; called by muse, mutect2, varscan2
- SMARCD3 | c.706G>A p.D236N (on ENST00000262188 / NM_001003801.2; = p.D223N on NM_003078.4) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99223416; called by muse, mutect2
- SMC3 | c.3179G>T p.G1060V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV100700081; called by muse, mutect2, varscan2
- SMO | c.807C>A p.Y269* | Nonsense Mutation (SNP) | VAF 18/135 reads (13%) | catalogued as COSV99977207; called by muse, mutect2, varscan2
- SNAP91 | c.1207C>G p.P403A | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.824); catalogued as COSV99536948; called by muse, mutect2, varscan2
- SNX4 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99305347; called by muse, mutect2, varscan2
- SPINK5 | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV99807598; called by muse, mutect2, varscan2
- SPRR1A | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 42/164 reads (26%) | catalogued as COSV61081881; called by muse, mutect2, varscan2
- SPTA1 | c.6217G>C p.V2073L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.152); catalogued as COSV100935756; called by muse, mutect2, varscan2
- SSX5 | c.374G>T p.G125V (on ENST00000347757 / NM_175723.1; = p.G166V on NM_021015.4) | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.211); catalogued as COSV100308925; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.254A>T p.N85I | Missense Mutation (SNP) | VAF 49/103 reads (48%) | PolyPhen possibly damaging (0.88); catalogued as COSV100085783; called by muse, mutect2, varscan2
- STAB2 | c.7345C>A p.P2449T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101186457; called by muse, mutect2, varscan2
- STX11 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs773008640, COSV100845543; called by muse, mutect2, varscan2
- SV2B | c.1867A>C p.R623= | Splice Region (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100371164; called by muse, varscan2
- SYNE1 | c.13321G>T p.V4441L (on ENST00000367255 / NM_182961.4; = p.V4370L on NM_033071.3) | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs1191241476, COSV99583457; called by muse, mutect2, varscan2
- SYNE1 | c.2102C>A p.A701D (on ENST00000367255 / NM_182961.4; = p.A708D on NM_033071.3) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99583501; called by muse, mutect2, varscan2
- SYT16 | c.77A>T p.E26V | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as COSV101413698; called by muse, mutect2, varscan2
- TBC1D9B | c.2030G>T p.S677I | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100783690; called by muse, mutect2
- TEX37 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV100304709; called by muse, mutect2, varscan2
- TMEM132B | c.1555C>A p.L519M | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54747910; called by muse, mutect2, varscan2
- TNFRSF11A | c.1293C>G p.C431W | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV54026319, COSV99500683; called by muse, mutect2, varscan2
- TNN | c.1853C>G p.T618R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99513304; called by muse, mutect2, varscan2
- TOMM70 | c.948A>T p.E316D | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.424); catalogued as COSV99424667; called by muse, mutect2, varscan2
- TRAPPC13 | c.707C>A p.T236K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.919); catalogued as COSV99199003; called by muse, mutect2, varscan2
- TRAPPC9 | c.3121G>T p.V1041L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101228534; called by muse, varscan2
- TRHDE | c.1495C>A p.L499M | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99672444, COSV99673046; called by muse, mutect2
- TRIM24 | c.1144-1G>T p.X382_splice | Splice Site (SNP) | VAF 29/103 reads (28%) | catalogued as rs1419649652, COSV100631373; called by muse, mutect2, varscan2
- TRIM27 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV101019517; called by muse, mutect2, varscan2
- TRPC5 | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.005); catalogued as rs775447821, COSV99463205; called by muse, mutect2, varscan2
- TTC13 | c.2236G>T p.D746Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100793063; called by muse, mutect2
- TTC17 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.036); catalogued as COSV99236290; called by muse, mutect2, varscan2
- TTLL6 | c.2258G>T p.W753L (on ENST00000393382 / NM_001130918.3; = p.W446L on NM_173623.3) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100938250; called by muse, mutect2, varscan2
- TTN | c.42807T>A p.N14269K (on ENST00000591111; = p.N6845K on NM_003319.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | PolyPhen probably damaging (0.997); catalogued as COSV100634667; called by muse, mutect2, varscan2
- TTPA | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99478662; called by muse, mutect2, varscan2
- TUBA3C | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.184); catalogued as COSV101262832, COSV101262855; called by muse, mutect2, varscan2
- TUBB1 | c.664T>C p.Y222H | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99414288; called by muse, mutect2, varscan2
- UGT3A2 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV99236939; called by muse, mutect2, varscan2
- UNC5C | c.1762T>A p.L588M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV101498075; called by muse, mutect2, varscan2
- UNC80 | c.593G>T p.R198M | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV99781413; called by muse, mutect2, varscan2
- UNC80 | c.594G>T p.R198S | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.985); catalogued as COSV99781415; called by muse, mutect2, varscan2
- UTRN | c.166A>T p.M56L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV100840746; called by muse, mutect2, varscan2
- VARS2 | c.3082C>T p.Q1028* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as COSV100423163; called by muse, mutect2, varscan2
- VGLL2 | c.932G>A p.C311Y (on ENST00000326274 / NM_182645.3; = p.C137Y on NM_153453.1) | Missense Mutation (SNP) | VAF 76/379 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV100410052; called by muse, mutect2, varscan2
- VIRMA | c.3676C>T p.L1226F | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99889746; called by muse, mutect2, varscan2
- VIRMA | c.3675G>T p.L1225F | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1233144752, COSV99889750; called by muse, mutect2, varscan2
- VPS16 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100988674; called by muse, mutect2, varscan2
- WASL | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99771924; called by muse, varscan2
- WDPCP | c.1398T>A p.F466L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV99707261; called by muse, mutect2, varscan2
- WNT5B | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs748214333, COSV100148866; called by muse, mutect2
- WWP2 | c.2566A>T p.K856* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100598847; called by muse, mutect2, varscan2
- XRN2 | c.2099A>G p.Y700C | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101018738; called by muse, mutect2, varscan2
- YY2 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.739); catalogued as COSV100810868; called by muse, mutect2, varscan2
- ZDBF2 | c.1206A>T p.R402S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as COSV100985686; called by muse, mutect2, varscan2
- ZFHX4 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51500124; called by muse, mutect2, varscan2
- ZFP57 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.654); catalogued as COSV100971994; called by muse, mutect2, varscan2
- ZNF225 | c.1745G>T p.S582I | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV99489645; called by muse, mutect2, varscan2
- ZNF260 | c.1003A>T p.K335* | Nonsense Mutation (SNP) | VAF 19/159 reads (12%) | catalogued as COSV101591079; called by muse, mutect2, varscan2
- ZNF33A | c.1685G>T p.S562I (on ENST00000458705 / NM_006974.3; = p.S563I on NM_006954.2) | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV100276296; called by muse, mutect2, varscan2
- ZNF473 | c.2119T>A p.C707S | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99569201; called by muse, mutect2, varscan2
- ZNF473 | c.2120G>T p.C707F | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54524292; called by muse, mutect2, varscan2
- ZNF804A | c.3412C>A p.L1138I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV100170673; called by muse, mutect2
- ZNF804B | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100306862; called by muse, mutect2, varscan2
- ZP2 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV99559915; called by mutect2, varscan2
- ZP4 | c.1403T>C p.F468S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100850805; called by muse, mutect2, varscan2
- ZZEF1 | c.2380C>G p.L794V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101068209, COSV67556379; called by muse, mutect2, varscan2
- ACOT7 | c.1089del p.R364Gfs*5 (on ENST00000377855 / NM_181864.3; = p.R354Gfs*5 on NM_007274.4) | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ANK2 | c.7430del p.K2477Rfs*2 | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | called by mutect2, pindel, varscan2
- ARL6IP4 | c.869A>G p.K290R (on ENST00000315580 / NM_018694.3; = p.K271R on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPN6 | c.184del p.H62Ifs*2 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | called by mutect2, pindel, varscan2
- CHFR | c.877G>A p.G293R (on ENST00000432561 / NM_001161345.1; = p.G252R on NM_018223.2) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.042); called by muse, mutect2
- CT45A1 | c.86A>T p.K29I | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CYFIP1 | c.2098G>C p.D700H | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DACT1 | c.2350dup p.W784Lfs*30 | Frame Shift Ins (INS) | VAF 56/187 reads (30%) | called by mutect2, pindel, varscan2
- FCGBP | c.11630A>G p.Y3877C | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GABRA6 | c.580del p.Y194Tfs*3 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- GDF10 | c.43del p.Q15Sfs*105 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- HOXA13 | c.1115_1117del p.N372del | In Frame Del (DEL) | VAF 68/338 reads (20%) | called by mutect2, pindel, varscan2
- IGHV3-66 | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 111/356 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGKV1D-8 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.672); called by muse, varscan2
- IGKV2-24 | c.161del p.G54Efs*5 | Frame Shift Del (DEL) | VAF 47/267 reads (18%) | called by mutect2, pindel, varscan2
- OR4S2 | c.805del p.V269Wfs*12 | Frame Shift Del (DEL) | VAF 75/320 reads (23%) | called by mutect2, pindel, varscan2
- OTX2 | c.338del p.K113Rfs*9 (on ENST00000408990 / NM_172337.3; = p.K121Rfs*9 on NM_021728.4) | Frame Shift Del (DEL) | VAF 44/156 reads (28%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.46); called by muse, varscan2
- PCLO | c.8446G>T p.A2816S | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2
- PLEC | c.11589_11635del p.Q3864Dfs*4 (on ENST00000322810 / NM_201380.4; = p.Q3754Dfs*4 on NM_000445.5) | Frame Shift Del (DEL) | VAF 12/124 reads (10%) | called by mutect2, pindel
- R3HDML | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- SLC4A3 | c.3412del p.A1138Qfs*10 | Frame Shift Del (DEL) | VAF 14/125 reads (11%) | called by mutect2, pindel, varscan2
- TNFSF10 | c.132+2_132+6del p.X44_splice | Splice Site (DEL) | VAF 16/92 reads (17%) | called by mutect2, pindel
- ABCC2 | c.240C>T p.A80= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV100965668; called by muse, mutect2, varscan2
- ADAMTS2 | c.3600T>C p.D1200= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV99284188; called by muse, mutect2, varscan2
- ADGRB1 | c.2559C>T p.I853= | Silent (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- ALG14 | c.600G>A p.P200= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs771908149, COSV100930907; called by muse, mutect2, varscan2
- AMBN | c.891T>A p.A297= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100534538; called by muse, mutect2, varscan2
- ANPEP | c.777A>G p.P259= | Silent (SNP) | VAF 37/275 reads (13%) | catalogued as COSV100263624; called by muse, mutect2, varscan2
- AQR | c.1500C>A p.G500= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99332984, COSV99334913; called by muse, mutect2
- ARHGAP20 | c.459C>G p.S153= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV99504874, COSV99505707; called by muse, mutect2, varscan2
- ARIH2 | c.720G>A p.Q240= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as rs1559838373, COSV100711441; called by muse, mutect2
- ATG2B | c.3927G>A p.V1309= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs779867911, COSV55892336, COSV99952283; called by muse, mutect2, varscan2
- CACNA1B | c.525C>A p.L175= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as COSV99500504; called by muse, mutect2, varscan2
- CELSR2 | c.780G>C p.T260= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs372864529; called by muse, mutect2, varscan2
- CLCNKB | c.339C>T p.S113= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100990511; called by muse, mutect2, varscan2
- CNKSR2 | c.1386T>C p.S462= | Silent (SNP) | VAF 50/143 reads (35%) | catalogued as COSV99670179; called by muse, mutect2, varscan2
- CORO7 | c.1239G>A p.A413= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs373254304, COSV99228250; called by muse, mutect2, varscan2
- CR1 | c.5646G>T p.L1882= | Silent (SNP) | VAF 35/209 reads (17%) | catalogued as rs748672006, COSV100888098; called by muse, mutect2, varscan2
- CRYGN | c.69C>G p.V23= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100484839; called by muse, mutect2, varscan2
- CTSW | c.627G>A p.L209= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV100327588, COSV57172763; called by muse, mutect2, varscan2
- DHX57 | c.1239C>T p.T413= | Silent (SNP) | VAF 34/201 reads (17%) | catalogued as COSV99770043; called by muse, mutect2, varscan2
- DNAH9 | c.6138C>A p.A2046= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV99308775; called by muse, mutect2, varscan2
- DSEL | c.1728G>T p.L576= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as COSV100026189; called by muse, mutect2, varscan2
- ELAVL4 | c.534C>T p.I178= | Silent (SNP) | VAF 60/167 reads (36%) | catalogued as COSV100836963, COSV100836964; called by muse, mutect2, varscan2
- EMILIN2 | c.2175G>A p.R725= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as COSV99599028; called by muse, mutect2, varscan2
- FAR2 | c.864A>G p.V288= | Silent (SNP) | VAF 64/167 reads (38%) | catalogued as COSV99479724; called by muse, mutect2, varscan2
- FAT4 | c.13146G>T p.G4382= | Silent (SNP) | VAF 120/342 reads (35%) | catalogued as COSV100630546; called by muse, mutect2, varscan2
- GAB4 | c.927G>T p.A309= | Silent (SNP) | VAF 34/185 reads (18%) | catalogued as COSV101272118; called by muse, mutect2, varscan2
- GGTLC1 | c.219C>G p.L73= | Silent (SNP) | VAF 22/203 reads (11%) | catalogued as COSV53847154, COSV99601021; called by muse, mutect2, varscan2
- GPNMB | c.234G>A p.V78= | Silent (SNP) | VAF 23/214 reads (11%) | catalogued as COSV99326914; called by muse, mutect2
- H4C7 | c.249C>T p.T83= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs200164073, COSV55100264; called by muse, mutect2, varscan2
- HERC2 | c.597G>T p.A199= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs753173937, COSV99877509; called by muse, mutect2, varscan2
- HSD11B2 | c.378C>A p.T126= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99341403; called by muse, mutect2, varscan2
- IGHV7-81 | c.90G>A p.V30= | Silent (SNP) | VAF 30/202 reads (15%) | called by muse, mutect2
- IGLON5 | c.396T>C p.P132= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99570940; called by muse, mutect2, varscan2
- IGLV3-21 | c.246C>A p.G82= | Silent (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- IL12RB2 | c.2394T>C p.D798= | Silent (SNP) | VAF 52/392 reads (13%) | catalogued as COSV99255793; called by muse, varscan2
- ITGA11 | c.1011C>A p.A337= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV100242298, COSV100242340; called by muse, mutect2, varscan2
- JAM3 | c.9G>T p.L3= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100138527; called by muse, mutect2
- JCAD | c.837C>T p.G279= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV100948629; called by muse, mutect2, varscan2
- KCNK10 | c.849G>A p.V283= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as COSV100069514; called by muse, mutect2
- KCNK13 | c.351T>C p.T117= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as rs1472604832, COSV99965999; called by muse, mutect2, varscan2
- KLHDC7B | c.1509C>A p.G503= (on ENST00000395676; = p.G1144= on NM_138433.5) | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as rs566545258, COSV101193000; called by muse, mutect2, varscan2
- KRT2 | c.942A>G p.K314= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100548694; called by muse, mutect2, varscan2
- KRT74 | c.888C>T p.I296= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs758888418, COSV99045100; called by muse, mutect2, varscan2
- LCE1E | c.222C>T p.G74= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as COSV100908583; called by muse, mutect2, varscan2
- LCP1 | c.1140A>G p.P380= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs1446734194, COSV100550123; called by muse, mutect2, varscan2
- LRP1 | c.13336C>A p.R4446= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV99677706; called by muse, mutect2, varscan2
- MCAM | c.879G>A p.E293= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs1174843079, COSV99877300; called by muse, mutect2, varscan2
- MED15 | c.1959C>A p.P653= (on ENST00000263205 / NM_001003891.3; = p.P613= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/188 reads (36%) | catalogued as COSV99488315; called by muse, mutect2, varscan2
- MFAP3L | c.358C>A p.R120= | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as rs777699021, COSV100852719; called by muse, mutect2, varscan2
- MMRN1 | c.3165G>T p.T1055= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs778903851, COSV53339284, COSV99307924; called by muse, mutect2, varscan2
- MUC16 | c.1791C>A p.G597= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV101202129; called by muse, mutect2, varscan2
- MYBL1 | c.1482A>G p.T494= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs1222179868, COSV101576570; called by muse, mutect2, varscan2
- MYH3 | c.1719G>A p.R573= | Silent (SNP) | VAF 68/178 reads (38%) | catalogued as COSV99879072; called by muse, mutect2, varscan2
- MYO3B | c.2436A>G p.K812= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs962923039, COSV100512114; called by muse, mutect2, varscan2
- NALCN | c.447T>C p.I149= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99218429; called by muse, mutect2, varscan2
- NAV3 | c.5676A>T p.T1892= (on ENST00000397909 / NM_001024383.2; = p.T1870= on NM_014903.6) | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV99896696; called by muse, mutect2
- NCR2 | c.192C>T p.I64= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV100897273; called by muse, mutect2, varscan2
- NFATC1 | c.1948C>T p.L650= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV53707607, COSV99502738; called by muse, mutect2, varscan2
- NIPBL | c.6552A>T p.S2184= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99243142; called by muse, mutect2, varscan2
- OBP2A | c.282G>T p.G94= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2
- OR11L1 | c.396C>T p.Y132= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100869508, COSV63315737; called by muse, mutect2, varscan2
- OR4C16 | c.438C>A p.A146= | Silent (SNP) | VAF 55/197 reads (28%) | catalogued as COSV58941747; called by muse, mutect2, varscan2
- OR5B12 | c.231C>A p.P77= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100222458; called by muse, mutect2, varscan2
- OR8H3 | c.189C>T p.F63= | Silent (SNP) | VAF 114/625 reads (18%) | catalogued as COSV57907319; called by muse, mutect2, varscan2
- P2RX3 | c.1161C>T p.S387= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV99629040; called by muse, mutect2, varscan2
- PCDHB9 | c.42C>A p.V14= | Silent (SNP) | VAF 46/161 reads (29%) | called by muse, mutect2, varscan2
- PDXDC1 | c.1224C>A p.V408= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100363525; called by muse, mutect2, varscan2
- PLEC | c.8235G>T p.A2745= (on ENST00000322810 / NM_201380.4; = p.A2635= on NM_000445.5) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs377752228, COSV100519910; called by muse, mutect2, varscan2
- POTEA | c.429G>A p.Q143= | Silent (SNP) | VAF 32/179 reads (18%) | called by muse, mutect2, varscan2
- PPP1R3A | c.1401T>C p.N467= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV99494679; called by muse, mutect2, varscan2
- PXDNL | c.1707C>T p.D569= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs375721225; called by muse, mutect2, varscan2
- RANBP2 | c.2766C>T p.H922= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99313568; called by muse, mutect2
- RAP2A | c.24G>T p.V8= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV99807412; called by muse, varscan2
- RASGEF1A | c.361C>T p.L121= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100988743; called by muse, mutect2
- ROS1 | c.1401C>T p.I467= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100877842; called by muse, mutect2, varscan2
- RPS6KA5 | c.903A>G p.R301= | Silent (SNP) | VAF 46/182 reads (25%) | catalogued as COSV100003389; called by muse, mutect2, varscan2
- RUBCN | c.630G>T p.L210= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99585311; called by muse, mutect2, varscan2
- RYR1 | c.10989G>T p.L3663= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100617284; called by muse, mutect2, varscan2
- SHROOM3 | c.4785G>A p.Q1595= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV99935629; called by muse, mutect2, varscan2
- SLC37A1 | c.1431C>T p.A477= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100721867; called by muse, mutect2, varscan2
- SRMS | c.1350C>A p.A450= | Silent (SNP) | VAF 73/180 reads (41%) | catalogued as COSV99420929; called by muse, mutect2
- ST8SIA3 | c.321T>C p.H107= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs1362238308, COSV100129743; called by muse, mutect2, varscan2
- SULT1C2 | c.462T>A p.G154= | Silent (SNP) | VAF 49/177 reads (28%) | catalogued as COSV99265494; called by muse, mutect2, varscan2
- TAB3 | c.1545A>G p.T515= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV99916938; called by muse, mutect2
- TBX10 | c.21T>A p.A7= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100106077; called by muse, mutect2, varscan2
- TECTA | c.4701A>G p.T1567= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV99881882; called by muse, mutect2, varscan2
- TOX2 | c.363C>T p.A121= (on ENST00000358131 / NM_001098798.2; = p.A70= on NM_032883.3) | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV57896789; called by muse, mutect2
- TPRA1 | c.945C>T p.A315= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV99952487; called by muse, mutect2, varscan2
- TRGV9 | c.156A>G p.A52= | Silent (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- TRHDE | c.1497G>A p.L499= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99673047; called by muse, mutect2
- TTC5 | c.114T>C p.D38= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV99352100; called by muse, mutect2, varscan2
- TTN | c.61575T>C p.Y20525= (on ENST00000591111; = p.Y13101= on NM_003319.4) | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs751453460, COSV100634665; called by muse, mutect2, varscan2
- TTN | c.38178T>A p.I12726= (on ENST00000591111; = p.I5302= on NM_003319.4) | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100624389, COSV100634675; called by muse, mutect2, varscan2
- TUBA3C | c.96C>A p.P32= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV67139556; called by muse, mutect2, varscan2
- UBAP2 | c.1158C>T p.G386= | Silent (SNP) | VAF 51/238 reads (21%) | catalogued as COSV100672057; called by muse, mutect2, varscan2
- UBE4B | c.3858G>A p.L1286= (on ENST00000343090 / NM_001105562.3; = p.L1157= on NM_006048.5) | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99477889; called by muse, mutect2, varscan2
- USP28 | c.840C>T p.P280= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as COSV99137125; called by muse, mutect2, varscan2
- UTP14C | c.1161A>T p.T387= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV101584410; called by muse, mutect2, varscan2
- VSIR | c.396C>T p.T132= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99824424; called by muse, mutect2, varscan2
- YIPF7 | c.825C>A p.A275= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs752318273, COSV100274711; called by muse, varscan2
- ZNF208 | c.2097C>T p.G699= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs766310386, COSV101237262; called by muse, mutect2, varscan2
- ZNF521 | c.832C>A p.R278= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV64122870, COSV64127125; called by muse, mutect2, varscan2
- ZSCAN10 | c.795T>C p.D265= (on ENST00000252463; = p.D320= on NM_032805.3) | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as COSV52969536; called by muse, mutect2, varscan2
- AC244258.1 | n.478A>G | RNA (SNP) | VAF 23/83 reads (28%) | catalogued as rs1252733503; called by muse, mutect2, varscan2
- AFDN | chr6:167826240 C>G | 5'Flank (SNP) | VAF 55/198 reads (28%) | catalogued as rs1386187998; called by muse, mutect2, varscan2
- CCDC28A | c.-144C>T | 5'UTR (SNP) | VAF 58/262 reads (22%) | catalogued as rs1378935533, COSV100236681; called by muse, mutect2, varscan2
- DNM2 | c.1336-990T>A | Intron (SNP) | VAF 26/78 reads (33%) | catalogued as COSV100118201; called by muse, mutect2, varscan2
- KIF16B | c.3498+3256T>G | Intron (SNP) | VAF 116/292 reads (40%) | catalogued as COSV100735013; called by muse, mutect2, varscan2
- NAIF1 | c.*2G>T | 3'UTR (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100895905; called by muse, mutect2, varscan2
- RPL4 | c.422-172G>A | Intron (SNP) | VAF 19/77 reads (25%) | catalogued as COSV100328997; called by muse, mutect2, varscan2
- SLC22A20P | n.856C>T | RNA (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- SLC25A3 | c.645-182del | Intron (DEL) | VAF 36/161 reads (22%) | called by mutect2, pindel, varscan2
- TTN | c.10361-3707A>T | Intron (SNP) | VAF 8/96 reads (8%) | catalogued as rs1245897922, COSV100634681, COSV60384754; called by muse, mutect2
- ZNF135 | c.-40A>T | 5'UTR (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99992200; called by muse, varscan2
